Somatic mutation profile of tumor specimen TCGA-5N-A9KI-01A (aliquot TCGA-5N-A9KI-01A-31D-A42E-08) from TCGA case TCGA-5N-A9KI, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 76.0 years (27,777 days).
Specimen TCGA-5N-A9KI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22ab1889-c55d-4ffe-a184-003a9136e82a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5N-A9KI-10A (Blood Derived Normal), aliquot TCGA-5N-A9KI-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84a434b9-2b55-420e-8ae6-70ef4792e665

The open-access MAF lists 192 somatic variants for this specimen: 141 protein-altering or splice-affecting, 47 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 47, Nonsense Mutation 12, Frame Shift Del 4, Splice Region 4, Frame Shift Ins 2, Intron 2, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2A | c.3790C>T p.R1264* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | hotspot (GDC flag); catalogued as rs1555039343, COSV63282990; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 19/55 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- RB1 | c.2501C>A p.S834* | Nonsense Mutation (SNP) | VAF 34/107 reads (32%) | catalogued as rs1131690906, CM144782, CM952105, COSV57310865, COSV99925872; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 34/49 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2M | c.1724C>G p.S575* | Nonsense Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV100588912; called by muse, mutect2, varscan2
- ABCA13 | c.2405G>A p.W802* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV101330130; called by muse, mutect2, varscan2
- ADGRF4 | c.698A>G p.N233S | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV51957349; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3857C>T p.P1286L | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV51857933; called by muse, mutect2, varscan2
- AQP5 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs763741727, COSV53311875; called by muse, mutect2, varscan2
- ARHGEF15 | c.2256C>G p.I752M | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV100730027, COSV62726415; called by muse, mutect2, varscan2
- ARMCX3 | c.201C>A p.S67R | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV57870554, COSV57871611; called by muse, mutect2, varscan2
- ARMCX3 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as COSV57869968; called by muse, mutect2, varscan2
- BSN | c.11174C>T p.S3725F | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV56526456, COSV56526984; called by muse, mutect2, varscan2
- CACNA2D1 | c.2532C>A p.N844K (on ENST00000356253 / NM_001366867.1; = p.N832K on NM_000722.4) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as COSV62391934; called by muse, mutect2, varscan2
- CADPS2 | c.2582G>A p.G861E | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0.196); catalogued as rs937633791, COSV57371931; called by muse, mutect2, varscan2
- CD109 | c.2382G>A p.M794I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV54656709; called by muse, mutect2, varscan2
- CDK12 | c.2710C>G p.P904A | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71002846; called by muse, mutect2, varscan2
- CHD8 | c.4426G>A p.E1476K (on ENST00000646647 / NM_001170629.2; = p.E1197K on NM_020920.4) | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV63219628; called by muse, mutect2, varscan2
- CHD8 | c.4306G>A p.D1436N (on ENST00000646647 / NM_001170629.2; = p.D1157N on NM_020920.4) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV63219632; called by muse, mutect2, varscan2
- CLCNKA | c.1653G>A p.M551I | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV58893841; called by muse, mutect2, varscan2
- COL17A1 | c.3448C>T p.P1150S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as rs1381983524, COSV100793307; called by muse, mutect2, varscan2
- CR2 | c.3011G>A p.R1004H | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.572); catalogued as rs765551048, COSV65509570; called by muse, mutect2, varscan2
- CRTC1 | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.364); catalogued as rs1309049735, COSV58723217; called by muse, mutect2, varscan2
- CXCR4 | c.716A>G p.K239R | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.933); catalogued as COSV54016867; called by muse, mutect2, varscan2
- DCP2 | c.859G>T p.D287Y | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV66618282; called by muse, mutect2, varscan2
- DDHD2 | c.1488C>G p.I496M | Missense Mutation (SNP) | VAF 70/213 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.361); catalogued as COSV68158777; called by muse, mutect2, varscan2
- DENND4C | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs768690648, COSV66823285; called by muse, mutect2, varscan2
- DHCR24 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as COSV64875476; called by muse, mutect2
- DMXL2 | c.2770G>T p.A924S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as rs755681885, COSV51856417, COSV99198350; called by mutect2, varscan2
- DPYSL5 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV56516075; called by muse, mutect2, varscan2
- ELF4 | c.1746G>T p.Q582H | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV57455002; called by muse, mutect2, varscan2
- ENOX1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0.01); catalogued as rs1363485759, COSV54910305, COSV54917884; called by muse, mutect2, varscan2
- ENOX2 | c.743C>G p.S248* (on ENST00000338144 / NM_001382520.1; = p.S219* on NM_006375.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 25/72 reads (35%) | catalogued as COSV100584488; called by muse, mutect2, varscan2
- ERICH6 | c.653T>C p.L218S | Missense Mutation (SNP) | VAF 90/188 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55803186; called by muse, mutect2
- F7 | c.995C>T p.T332M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs200212201, CM002767, COSV60646513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM3C | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.099); catalogued as COSV63436520; called by muse, mutect2, varscan2
- FAM47C | c.2014G>C p.E672Q | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.493); catalogued as COSV100792907, COSV63730339; called by muse, mutect2, varscan2
- FBN3 | c.4547G>A p.R1516Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs201893883, COSV54472460; called by muse, mutect2, varscan2
- FBXO9 | c.1267G>C p.E423Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.093); catalogued as COSV99762611; called by muse, mutect2, varscan2
- FDCSP | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.934); catalogued as COSV58765337; called by muse, mutect2, varscan2
- FLNA | c.3902C>T p.S1301L | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV61051104; called by muse, mutect2, varscan2
- FOXO4 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1364000621, COSV100447036; called by muse, mutect2, varscan2
- FRY | c.8476G>A p.E2826K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV66511055; called by muse, mutect2
- GALNT17 | c.1141C>T p.R381W | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758121306, COSV100353306, COSV61160204; called by muse, mutect2, varscan2
- GEMIN4 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 80/105 reads (76%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.851); catalogued as rs757149711, COSV56746688; called by muse, mutect2, varscan2
- GJA8 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1553242756, CM135085, COSV53787998; called by muse, mutect2, varscan2
- GNAI3 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766607222, COSV63984496; called by muse, mutect2, varscan2
- GON4L | c.3032C>G p.S1011C | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV55203724; called by muse, mutect2, varscan2
- HCRTR2 | c.779C>G p.S260C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1316498171, COSV63799019; called by muse, mutect2, varscan2
- HEPACAM2 | c.124del p.H42Mfs*43 (on ENST00000394468 / NM_001039372.4; = p.H30Mfs*43 on NM_198151.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as COSV59062573; called by mutect2, pindel, varscan2
- HEPHL1 | c.351G>C p.K117N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV59893776, COSV59896274, COSV59896955; called by muse, mutect2, varscan2
- HK1 | c.2251G>A p.G751S | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53857320; called by muse, mutect2, varscan2
- HMCN1 | c.4513G>C p.D1505H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as COSV54940037; called by muse, mutect2, varscan2
- HMGCLL1 | c.422A>G p.H141R | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs771849840, COSV51444145, COSV51451752; called by muse, mutect2, varscan2
- HOXB1 | c.788G>C p.R263P | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV53317498, COSV53318636; called by muse, mutect2, varscan2
- HOXC9 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57717368; called by muse, mutect2, varscan2
- HPS1 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as COSV100282777; called by muse, mutect2, varscan2
- HSD11B2 | c.476C>T p.T159I | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV52099841; called by muse, mutect2, varscan2
- HSPA8 | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.678); catalogued as COSV57085995, COSV57086420; called by muse, mutect2
- HYAL3 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs377396269; called by muse, mutect2, varscan2
- ICE1 | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as COSV56832063; called by muse, mutect2, varscan2
- IFTAP | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs181985480, COSV57557751; called by muse, mutect2, varscan2
- IL10RA | c.189G>A p.R63= | Splice Region (SNP) | VAF 10/42 reads (24%) | catalogued as rs1565370880, COSV57141695, COSV57142062; called by muse, mutect2, varscan2
- ITPK1 | c.770C>G p.P257R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50896533, COSV99968439; called by muse, mutect2, varscan2
- ITPRID1 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs779921596, COSV60082401; called by muse, mutect2, varscan2
- KANK4 | c.2078G>T p.S693I | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV62989259; called by muse, mutect2, varscan2
- KIF11 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53273955; called by muse, mutect2, varscan2
- KLHL1 | c.568C>G p.Q190E | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.017); catalogued as COSV64783534; called by muse, mutect2, varscan2
- LHFPL6 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1205353196, COSV65449510; called by muse, mutect2, varscan2
- LRRC17 | c.1274A>G p.H425R | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.024); catalogued as rs893506993, COSV50867871; called by muse, mutect2, varscan2
- LRRTM1 | c.1447A>T p.M483L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1392175260, COSV54446434; called by muse, mutect2, varscan2
- MACF1 | c.19093G>A p.A6365T (on ENST00000372915; = p.A4410T on NM_012090.5) | Missense Mutation (SNP) | VAF 31/84 reads (37%) | catalogued as COSV57143199; called by muse, mutect2, varscan2
- MAGEB6B | c.854C>A p.S285* | Nonsense Mutation (SNP) | VAF 25/117 reads (21%) | catalogued as COSV69689955; called by muse, mutect2, varscan2
- MAP3K15 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 32/72 reads (44%) | catalogued as rs370173616, COSV100135461; called by muse, mutect2, varscan2
- MASP1 | c.902G>T p.C301F | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV51463753; called by muse, mutect2
- MEF2C | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 78/123 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as COSV60931144; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1825G>C p.D609H | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56624596; called by muse, mutect2, varscan2
- MROH9 | c.1423del p.D475Tfs*32 | Frame Shift Del (DEL) | VAF 59/146 reads (40%) | catalogued as COSV100882921; called by mutect2, pindel, varscan2
- MTHFD2 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV51202379; called by muse, mutect2, varscan2
- MUC4 | c.15582G>A p.S5194= (on ENST00000463781 / NM_018406.7; = p.S958= on NM_004532.6) | Splice Region (SNP) | VAF 10/70 reads (14%) | catalogued as rs372933950, COSV57774625; called by muse, mutect2
- MYF5 | c.592A>G p.K198E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.334); catalogued as COSV57356549; called by muse, mutect2, varscan2
- MZT1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.899); catalogued as COSV64698248; called by muse, mutect2, varscan2
- NANOS3 | c.307G>A p.A103T (on ENST00000397555; = p.A122T on NM_001098622.2) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310054421, COSV100188538; called by muse, mutect2
- NIN | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1266256173, COSV55405604; called by muse, mutect2, varscan2
- NIN | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99814867; called by muse, mutect2, varscan2
- NRCAM | c.1714G>A p.D572N (on ENST00000379028 / NM_001371124.1; = p.D566N on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61048559; called by muse, mutect2, varscan2
- NRK | c.4404G>T p.L1468F | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV54606342, COSV99689140; called by muse, mutect2, varscan2
- NTRK1 | c.535G>C p.G179R | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV62328565; called by muse, mutect2, varscan2
- OPHN1 | c.404A>T p.E135V | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV62786780; called by muse, mutect2, varscan2
- OR2T33 | c.237G>T p.M79I | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV58817839; called by muse, mutect2, varscan2
- OR5D14 | c.661G>C p.V221L | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV59458673; called by muse, mutect2
- PDE3A | c.1357T>A p.L453M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.944); catalogued as COSV62982513; called by muse, mutect2, varscan2
- PDIA4 | c.837G>C p.M279I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as rs1423260950, COSV53726787; called by muse, mutect2, varscan2
- PHF21A | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57659762; called by muse, mutect2, varscan2
- PHF24 | c.601T>C p.Y201H | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.914); catalogued as COSV54276802; called by muse, mutect2, varscan2
- PHKB | c.1652G>A p.G551E | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1461357901, COSV54533647; called by muse, mutect2, varscan2
- PHRF1 | c.3355C>T p.R1119W (on ENST00000264555 / NM_001286581.2; = p.R1118W on NM_020901.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs373913435; called by muse, mutect2, varscan2
- PIK3CA | c.821G>A p.R274K | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as rs150606403, COSV55992931; called by muse, mutect2, varscan2
- POLR1D | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1189463043, COSV57256642; called by muse, mutect2, varscan2
- PPARGC1A | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.13); catalogued as COSV53524671; called by muse, mutect2, varscan2
- PRDM16 | c.1870G>A p.D624N | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV54580933, COSV54607748, COSV54607942; called by muse, mutect2, varscan2
- PRKCB | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs748776658, COSV57767165, COSV57769485; called by muse, mutect2, varscan2
- PTPRJ | c.1942T>G p.F648V | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.145); catalogued as COSV69254584; called by muse, mutect2, varscan2
- PTPRZ1 | c.4352del p.S1451Yfs*5 | Frame Shift Del (DEL) | VAF 23/73 reads (32%) | catalogued as COSV66445263; called by mutect2, pindel, varscan2
- RAP2C | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV61683695; called by muse, mutect2, varscan2
- RB1 | c.2123T>A p.M708K | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57326888; called by muse, mutect2, varscan2
- RGS12 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.119); catalogued as COSV60910091; called by muse, mutect2, varscan2
- RHOXF1 | c.278T>A p.M93K | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.022); catalogued as COSV54295738; called by muse, mutect2, varscan2
- RICTOR | c.4060C>T p.P1354S | Missense Mutation (SNP) | VAF 100/176 reads (57%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.592); catalogued as COSV57130380; called by muse, mutect2, varscan2
- RIN2 | c.1153G>C p.E385Q (on ENST00000255006 / NM_001242581.1; = p.E336Q on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV54794034; called by muse, mutect2, varscan2
- RNASET2 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); catalogued as COSV99218645; called by muse, mutect2
- RNF150 | c.1103C>T p.T368I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs1235844758, COSV60799316; called by muse, mutect2, varscan2
- RNF17 | c.3923T>C p.I1308T | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV55050948; called by muse, mutect2, varscan2
- RNF220 | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV59190287; called by muse, mutect2, varscan2
- SBF2 | c.513G>A p.Q171= | Splice Region (SNP) | VAF 30/178 reads (17%) | catalogued as COSV56291628; called by muse, mutect2, varscan2
- SBF2 | c.512A>T p.Q171L | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV56307233, COSV56311107; called by muse, mutect2, varscan2
- SENP6 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as rs769255313, COSV59194541; called by muse, mutect2, varscan2
- SLC22A9 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54170297; called by muse, mutect2, varscan2
- SLC35G3 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as rs1365396709, COSV52012703; called by muse, mutect2, varscan2
- SLC5A4 | c.1765G>T p.E589* | Nonsense Mutation (SNP) | VAF 35/98 reads (36%) | catalogued as COSV56673912, COSV99832104; called by muse, mutect2, varscan2
- SMARCA1 | c.1710T>A p.F570L | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64413775; called by muse, mutect2, varscan2
- SPAG16 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs142357329; called by muse, mutect2, varscan2
- SRCAP | c.8604G>T p.R2868S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as rs1483823600, COSV52680845; called by muse, mutect2, varscan2
- SSTR4 | c.306C>G p.F102L | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs760734260, COSV54796978, COSV54800138; called by muse, mutect2, varscan2
- SSTR4 | c.307G>T p.V103L | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs770559332, COSV54800149; called by muse, mutect2, varscan2
- STARD13 | c.790G>A p.E264K (on ENST00000336934 / NM_001243476.3; = p.E146K on NM_052851.3) | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV55236404; called by muse, mutect2, varscan2
- STK17B | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.309); catalogued as rs755874663, COSV55830110; called by muse, mutect2, varscan2
- TARBP1 | c.1378C>A p.L460I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.084); catalogued as rs1470310276, COSV50205282; called by muse, mutect2, varscan2
- TLL1 | c.1438G>A p.D480N | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1354791371, COSV50277077, COSV50321073, COSV99287454; called by muse, mutect2, varscan2
- TLL1 | c.2782C>T p.R928* | Nonsense Mutation (SNP) | VAF 10/118 reads (8%) | catalogued as rs569659122, COSV99288024; called by muse, mutect2
- UBN2 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56035217; called by muse, mutect2, varscan2
- USP10 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.614); catalogued as COSV54752853; called by muse, mutect2, varscan2
- USP33 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV62471369; called by muse, mutect2, varscan2
- USP34 | c.9451C>G p.L3151V | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.91); PolyPhen benign (0.062); catalogued as rs1358512527, COSV68406317; called by muse, mutect2, varscan2
- VWA8 | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as rs1305339581, COSV55703397; called by muse, varscan2
- ZMYND10 | c.1122G>A p.R374= | Splice Region (SNP) | VAF 9/32 reads (28%) | catalogued as COSV51603995; called by muse, mutect2, varscan2
- ZNF81 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as COSV58578610; called by muse, mutect2, varscan2
- ARID1A | c.2219_2227del p.S740_Q743delins* | Nonsense Mutation (DEL) | VAF 13/44 reads (30%) | called by mutect2, varscan2
- CORIN | c.526dup p.T176Nfs*23 | Frame Shift Ins (INS) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- PKLR | c.867del p.A291Pfs*30 | Frame Shift Del (DEL) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- TMCO5A | c.668dup p.I224Dfs*58 | Frame Shift Ins (INS) | VAF 33/96 reads (34%) | called by mutect2, pindel, varscan2
- AGAP6 | c.528G>A p.V176= (on ENST00000374056 / NM_001365867.1; = p.V199= on NM_001077665.2) | Silent (SNP) | VAF 26/142 reads (18%) | called by muse, varscan2
- ALG10B | c.801T>C p.F267= | Silent (SNP) | VAF 56/158 reads (35%) | catalogued as COSV58144848; called by muse, mutect2, varscan2
- AUP1 | c.435C>T p.F145= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs1461037422, COSV51213739; called by muse, mutect2, varscan2
- BAP1 | c.366C>T p.F122= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs17849500, COSV99964388; called by muse, varscan2
- BFAR | c.429A>T p.G143= | Silent (SNP) | VAF 38/189 reads (20%) | catalogued as COSV55494484; called by muse, mutect2, varscan2
- BOD1L1 | c.2361C>G p.T787= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV50061448; called by muse, mutect2, varscan2
- CADPS | c.1230C>T p.L410= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV51901675; called by muse, mutect2, varscan2
- CARF | c.1284A>G p.L428= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as COSV57549929; called by muse, mutect2, varscan2
- CCDC18 | c.1623G>A p.L541= (on ENST00000343253 / NM_001306076.1; = p.L542= on NM_206886.4) | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV58147597; called by muse, mutect2, varscan2
- CDH23 | c.2529G>A p.E843= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs1465586681, COSV54952050; called by muse, mutect2, varscan2
- CWH43 | c.363C>T p.L121= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV56935976, COSV56943897; called by muse, mutect2, varscan2
- DNAH5 | c.8307G>A p.L2769= | Silent (SNP) | VAF 7/120 reads (6%) | catalogued as COSV54250813; called by muse, mutect2
- DNAJB11 | c.960C>T p.I320= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV54002793; called by muse, mutect2, varscan2
- DRD5 | c.1200C>T p.I400= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs866493427, COSV58580341, COSV58580483; called by muse, mutect2, varscan2
- DYNC2I1 | c.1974C>G p.V658= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV68107183; called by muse, mutect2, varscan2
- EPPIN | c.42C>A p.V14= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV51491905; called by muse, mutect2, varscan2
- EXOSC1 | c.105G>T p.S35= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV61749749; called by muse, mutect2, varscan2
- FFAR3 | c.660G>A p.Q220= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as rs1305668584, COSV59909658; called by muse, mutect2, varscan2
- FRAS1 | c.8001C>T p.I2667= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV53645920; called by muse, mutect2, varscan2
- GJA8 | c.372G>A p.P124= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs782036781, COSV53789149, COSV53790561; called by muse, mutect2, varscan2
- HCAR2 | c.546C>T p.I182= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV61025795; called by muse, mutect2, varscan2
- HDAC9 | c.646C>A p.R216= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV67784830; called by muse, mutect2, varscan2
- IGLV10-54 | c.225C>T p.P75= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV101135440; called by muse, mutect2, varscan2
- ITGB6 | c.1092C>T p.I364= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV51798498; called by muse, mutect2, varscan2
- KCNH6 | c.2655G>A p.G885= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV59005799; called by muse, mutect2, varscan2
- KLHL10 | c.1485G>A p.R495= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV53174986; called by muse, mutect2, varscan2
- MMP16 | c.6C>T p.I2= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV54165771, COSV99689934; called by muse, mutect2
- MTOR | c.3636C>T p.L1212= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV63868644; called by muse, mutect2, varscan2
- MUC2 | c.63G>C p.P21= | Silent (SNP) | VAF 29/149 reads (19%) | catalogued as rs575179256; called by muse, mutect2, varscan2
- NBPF26 | c.4143C>G p.V1381= (on ENST00000620612; = p.V1119= on NM_001351372.1) | Silent (SNP) | VAF 89/296 reads (30%) | called by muse, mutect2, varscan2
- NR2F2 | c.354C>T p.N118= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV67684104; called by muse, mutect2, varscan2
- OR2F2 | c.189C>A p.L63= | Silent (SNP) | VAF 40/261 reads (15%) | catalogued as COSV68833323; called by muse, mutect2, varscan2
- POP1 | c.2538G>A p.L846= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV62894116; called by muse, mutect2, varscan2
- PRMT7 | c.315G>A p.K105= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV59835620; called by muse, mutect2, varscan2
- RAPGEF5 | c.1380G>A p.G460= (on ENST00000401957 / NM_001367602.2; = p.G763= on NM_012294.5) | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100687648; called by muse, mutect2
- RPTOR | c.936G>A p.L312= | Silent (SNP) | VAF 79/220 reads (36%) | catalogued as COSV60818138; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.267G>A p.L89= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100602999; called by muse, mutect2, varscan2
- TENM1 | c.3105G>C p.G1035= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV64442518; called by muse, mutect2, varscan2
- TENM1 | c.2784G>T p.V928= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as COSV64442531; called by muse, mutect2, varscan2
- THADA | c.1950G>C p.R650= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV57692962; called by muse, mutect2, varscan2
- TMCO3 | c.1809G>A p.P603= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as rs745530480, COSV64809230; called by muse, mutect2, varscan2
- TP53 | c.744G>A p.R248= | Silent (SNP) | VAF 33/48 reads (69%) | catalogued as COSV52782654, COSV53050697, COSV53372256; called by muse, mutect2, varscan2
- USP53 | c.2079C>T p.H693= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV56797579; called by muse, mutect2
- WDR27 | c.2106C>T p.I702= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs777006582, COSV61216839; called by muse, mutect2, varscan2
- ZC3H11A | c.834G>A p.L278= | Silent (SNP) | VAF 62/107 reads (58%) | catalogued as rs1304583379, COSV59750100; called by muse, mutect2, varscan2
- ZFYVE26 | c.3417C>G p.G1139= | Silent (SNP) | VAF 27/41 reads (66%) | catalogued as COSV61333384; called by muse, mutect2
- ZNF236 | c.1815G>A p.K605= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV53495000; called by muse, mutect2, varscan2
- ACE | c.1922-264G>A | Intron (SNP) | VAF 10/20 reads (50%) | catalogued as COSV99327597; called by muse, mutect2, varscan2
- CMTM1 | c.81+320C>T | Intron (SNP) | VAF 12/42 reads (29%) | catalogued as rs1223843794, COSV50451744; called by muse, mutect2, varscan2
- PYY3 | n.99C>A | RNA (SNP) | VAF 4/15 reads (27%) | catalogued as rs782506237; called by muse, mutect2, varscan2
- ZBTB37 | chr1:173866891 G>A | 5'Flank (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
